Somatic mutation profile of tumor specimen 0DQQBX from CCDI case PBCFIU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (637 days).
Specimen 0DQQBX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 438eecd9-8960-4435-a6d9-b5ae27e518e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0a2ca51-f921-46f0-984c-2284067e0347

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPR3 | c.4060G>A p.D1354N | Missense Mutation (SNP) | VAF 33/493 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs1234139659; called by muse, mutect2
- KATNA1 | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 193/449 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59503756; called by muse, mutect2, varscan2
- SSC5D | c.3916G>C p.D1306H | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.011); catalogued as rs201344068; called by mutect2, varscan2
- CRACR2A | c.1012C>A p.Q338K | Missense Mutation (SNP) | VAF 43/552 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- HTR5A | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RABGAP1 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 62/667 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2
- TRIM6-TRIM34 | c.1447C>A p.H483N | Missense Mutation (SNP) | VAF 98/556 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- WDR11 | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 15/521 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- TUBA3C | c.-49G>A | 5'UTR (SNP) | VAF 148/340 reads (44%) | catalogued as rs367873347; called by muse, mutect2, varscan2
